Somatic mutation profile of tumor specimen TCGA-28-2510-01A (aliquot TCGA-28-2510-01A-01D-1696-08) from TCGA case TCGA-28-2510, project TCGA-GBM (Glioblastoma Multiforme).
Specimen TCGA-28-2510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07e0242f-839c-4aca-b4db-da36d2773bf1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-2510-10A (Blood Derived Normal), aliquot TCGA-28-2510-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecda772b-48b7-49d8-92c1-6248a72f9454

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 17/125 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC004593.2 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); catalogued as rs528035980; called by muse, mutect2, varscan2
- AHNAK | c.5879T>C p.V1960A | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV57214181; called by muse, mutect2, varscan2
- CCDC172 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs748847947, COSV60938304; called by muse, mutect2, varscan2
- GTF3C1 | c.4948G>A p.G1650S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100649847; called by muse, mutect2
- HIPK4 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as rs1325764906; called by muse, mutect2, varscan2
- RIMBP2 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1020820815, COSV55464560; called by muse, mutect2, varscan2
- SAMD9 | c.3548C>T p.P1183L | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1480540811, COSV101180303; called by muse, mutect2, varscan2
- STAB2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.722); catalogued as rs200600511; called by muse, mutect2, varscan2
- YY2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 98/323 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs746989221; called by muse, mutect2, varscan2
- ADAM10 | c.1606T>G p.C536G | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AJUBA | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.071); called by muse, mutect2
- CLCN3 | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FLG | c.7297A>G p.T2433A | Missense Mutation (SNP) | VAF 40/309 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HMCN1 | c.9535C>T p.P3179S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LIN54 | c.200C>G p.T67R | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LRPPRC | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2
- OR7A5 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- SPTBN4 | c.5023G>A p.E1675K | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.983); called by muse, mutect2
- CTAGE1 | c.9C>T p.P3= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV101194459, COSV66943287; called by muse, mutect2, varscan2
- CUX2 | c.1623C>T p.G541= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs750439909, COSV55624883; called by mutect2, varscan2
- LPXN | c.384G>A p.L128= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- NID2 | c.1962C>T p.Y654= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1000706591, COSV53492518; called by muse, mutect2
- NLRP4 | c.1905C>A p.T635= | Silent (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- RBM25 | c.2085T>C p.F695= | Silent (SNP) | VAF 21/83 reads (25%) | called by muse, mutect2, varscan2
- SNX29 | c.1425G>A p.V475= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.9126T>C p.A3042= (on ENST00000591111; = p.A2996= on NM_003319.4) | Silent (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
